Somatic mutation profile of tumor specimen 0DLDZP from CCDI case PBBZGR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 7.6 years (2,791 days).
Specimen 0DLDZP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 826050a7-50d7-4742-8cce-0fef37f3ff04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DLDZD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a6dd1010-0465-46ec-a9b4-de2f1ed3ddda

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1, 3'UTR 1, Nonsense Mutation 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAAH2 | c.1140G>C p.L380F | Missense Mutation (SNP) | VAF 170/191 reads (89%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.568); catalogued as rs370664625; called by muse, mutect2, varscan2
- HIP1R | c.1053C>T p.D351= | Splice Region (SNP) | VAF 161/424 reads (38%) | catalogued as rs1045743664; called by muse, mutect2, varscan2
- KLF7 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 42/479 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.17); catalogued as COSV58742149; called by muse, mutect2
- KLHL33 | c.220C>G p.R74G | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.02); catalogued as COSV100754999, COSV60727056; called by muse, mutect2, varscan2
- LPAR3 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 77/648 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as rs777871234, COSV65454878; called by muse, mutect2, varscan2
- MRM2 | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 155/314 reads (49%) | catalogued as COSV54248808; called by muse, mutect2, varscan2
- NAALADL2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 202/346 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767946652, COSV70296669; called by muse, mutect2, varscan2
- COL6A5 | c.3432T>G p.D1144E | Missense Mutation (SNP) | VAF 24/509 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.438); called by muse, mutect2
- ZMYM5 | c.872+2T>G p.X291_splice | Splice Site (SNP) | VAF 21/260 reads (8%) | called by muse, mutect2
- KIAA1109 | c.12612C>T p.N4204= | Silent (SNP) | VAF 208/464 reads (45%) | catalogued as COSV52682970; called by muse, mutect2, varscan2
- MYH1 | c.5115C>T p.I1705= | Silent (SNP) | VAF 269/674 reads (40%) | catalogued as rs145122906, COSV56844388; called by muse, mutect2, varscan2
- MELTF | c.712+48G>T | Intron (SNP) | VAF 97/237 reads (41%) | called by muse, mutect2, varscan2
- MLN | c.*44C>T | 3'UTR (SNP) | VAF 12/368 reads (3%) | called by muse, mutect2
